TCGA case TCGA-A2-A04Y — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Walter Reed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9ce7ce09-4409-4fa3-9f78-b2b24716f860

Demographics
Sex at birth: female; Race: white; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 53.5 years (19,533 days); Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N1mi; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 13; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 135 days; Number of cycles: 4; Treatment dose: 4,800 mg; Prescribed dose: 1200; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 93 days; Days to treatment end: 135 days; Number of cycles: 4; Treatment dose: 480 mg; Prescribed dose: 120; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 149 days; Days to treatment end: 226 days; Number of cycles: 12; Treatment dose: 3,900 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Days to treatment start: 149 days; Days to treatment end: 659 days (1.8 years); Number of cycles: 22; Treatment dose: 10,037 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 251 days; Days to treatment end: 290 days; Treatment dose: 5,040 cGy; Treatment outcome: Complete Response; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 273 days; Days to treatment end: 371 days (1.0 years); Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 293 days; Days to treatment end: 297 days; Treatment dose: 1,000 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 372 days (1.0 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 1; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Bisphosphonate Therapy; Therapeutic agents: Zoledronic Acid; Days to treatment start: 503 days (1.4 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 4; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
2. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Synchronous primary; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA.
   Recorded as not given: Pharmaceutical Therapy, NOS (Anastrozole); Pharmaceutical Therapy, NOS (Doxorubicin Hydrochloride); Pharmaceutical Therapy, NOS (Paclitaxel); Radiation Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen); Pharmaceutical Therapy, NOS (Trastuzumab); Pharmaceutical Therapy, NOS (Zoledronic Acid).

Follow-up (2 entries)
- Days to follow up: 764 days (2.1 years); Disease response: Tumor Free.
- Days to follow up: 1,099 days (3.0 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1.13; Specialized molecular test: Signal ratio.
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Positive; Test value range: 10-19%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A2-A04Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-A2-A04Y-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 17; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-A2-A04Y-01A-02-MS2: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 17; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-A2-A04Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A2-A04Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Initial weight: 180 mg.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 1.13; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Her2 IHC score: 1+; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 0; Er positivity scale other: Strong; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 4; Pharmaceutical therapy drug name: Herceptin.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 4: Regimen number: 7; Pharmaceutical therapy drug name: Zometa; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Patient has oesteoporosis (Prevention of further bone loss.
- Drug treatment 5: Regimen number: 3; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 6: Regimen number: 5.
- Drug treatment 6, Route of administrations: Route of administration: PO.
- Drug treatment 7: Regimen number: 6; Pharmaceutical therapy drug name: Arimidex.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Infiltrating Ductal Carcinoma.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: 31.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Adriamycin.
- Other malignancy form, Drug treatment, Administered drug 3: Pharmaceutical therapy drug name: Taxol.
- Other malignancy form, Drug treatment, Administered drug 4: Pharmaceutical therapy drug name: Herceptin.
- Other malignancy form, Drug treatment, Administered drug 6: Pharmaceutical therapy drug name: Arimidex.
- Other malignancy form, Drug treatment, Administered drug 7: Pharmaceutical therapy drug name: Zometa (Bisphosphonate therapy).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,099 days; disease-specific survival: no event (censored), 1,099 days; disease-free interval: no event (censored), 1,099 days; progression-free interval: no event (censored), 1,099 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A2-A04Y-01A-21D-A036-01): tumor purity 0.6, ploidy 2.12, whole-genome doublings 0.
